CCDI case PBCCDJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/94a323ee-d5ac-4bd4-abcd-4385b6546e0c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.9 years (5,068 days).

Biospecimens (3 samples)
- Sample 0DOJUS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOJXS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DOJY3: Tissue type: Tumor; Specimen type: Solid Tissue.
